Surgical pathology report (de-identified scan), TCGA case TCGA-HT-8106, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-8106-01A (Primary Tumor).

██████ path report

Microscopic

Sections demonstrate a mildly to moderately hypercellular glial neoplasm, the cells of which resemble moderately to markedly atypical fibrillar and gemistocytic astrocytes. There is prominent multifocal perivascular lymphocytic inflammation. Neither oligodendroglioma nor ganglion cell differentiation is seen. No microvascular proliferation or necrosis is identified. Whereas no mitotic figures are identified, in what appears to be a purely astrocytic lineage tumor, the atypia alone is sufficient for classification as anaplastic grade 3. However, MIB-1 immunohistochemistry will be performed to better assess tumor proliferative activity.

Addendum

Numberous MIB-1 reactive cells are present throughout the specimen. The labeling index of 16.3% is calculated, consistent with the otherwise high grade histologic features

Diagnosis

Anaplastic astrocytoma grade 3

Source: NCI Genomic Data Commons file 14c04fe3-2534-43d3-8cc2-3b3f98a6e5b8 (TCGA-HT-8106.AEBC4408-92F6-404C-B9E6-9BB7E46C700F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).